Somatic mutation profile of tumor specimen TCGA-D8-A1XF-01A (aliquot TCGA-D8-A1XF-01A-11D-A14G-09) from TCGA case TCGA-D8-A1XF, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 46.0 years (16,787 days).
Specimen TCGA-D8-A1XF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0721c388-c7ce-4470-b3b2-05c59a7d15f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1XF-10A (Blood Derived Normal), aliquot TCGA-D8-A1XF-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/470cc361-8525-493b-b607-87d962c44a42

The open-access MAF lists 41 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 28, Silent 10, Frame Shift Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABI2 | c.1456G>A p.D486N (on ENST00000295851 / NM_001375719.1; = p.D448N on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/76 reads (89%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53693400; called by muse, mutect2, varscan2
- C2CD3 | c.4871C>T p.T1624M | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as rs774712341, COSV100486616; called by muse, mutect2
- CUL4A | c.1305G>C p.K435N (on ENST00000375440 / NM_001008895.4; = p.K335N on NM_003589.3) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV58373635; called by muse, mutect2, varscan2
- DLC1 | c.878G>A p.G293D | Missense Mutation (SNP) | VAF 73/87 reads (84%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs745492706, COSV52309716; called by muse, mutect2, varscan2
- DOCK3 | c.1351C>A p.L451I | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as COSV56520189, COSV56528558; called by muse, mutect2, varscan2
- FLG | c.9362G>T p.R3121M | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64243171; called by muse, mutect2, varscan2
- HRNR | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765009680, COSV64256268, COSV64261244; called by muse, mutect2, varscan2
- HRNR | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.17); catalogued as COSV64259269; called by muse, mutect2, varscan2
- KIAA0319 | c.1275G>T p.K425N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.3); catalogued as COSV65499423; called by muse, mutect2, varscan2
- KLK14 | c.67A>G p.N23D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV50068998; called by muse, mutect2, varscan2
- MACF1 | c.18886G>A p.A6296T (on ENST00000372915; = p.A4341T on NM_012090.5) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV57127205; called by muse, mutect2, varscan2
- MED25 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 4/6 reads (67%) | SIFT tolerated (0.38); PolyPhen benign (0.041); catalogued as rs775622130, COSV57205357; ClinVar: uncertain significance; called by mutect2, varscan2
- MTM1 | c.302G>T p.S101I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV60335553; called by muse, mutect2
- MUC16 | c.29308G>A p.E9770K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.263); catalogued as rs190716296, COSV67473734, COSV67481580; called by muse, mutect2, varscan2
- MYLK | c.1310T>G p.V437G | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60613035; called by muse, mutect2, varscan2
- NLRP3 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV60226249; called by muse, mutect2, varscan2
- OSBPL8 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1273524556, COSV53884279; called by muse, mutect2, varscan2
- PPRC1 | c.218T>A p.L73Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV53386237; called by muse, mutect2, varscan2
- PRELP | c.77C>A p.P26Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV58116262; called by muse, mutect2, varscan2
- RAD1 | c.623A>G p.D208G | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV57715343; called by muse, mutect2, varscan2
- SARDH | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs779062783, COSV64100020; called by muse, mutect2
- SLC13A3 | c.550C>G p.R184G | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV51717449, COSV99286130; called by muse, mutect2, varscan2
- SLC19A3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 15/15 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1347868865, COSV51453239; called by muse, mutect2, varscan2
- SPTBN2 | c.5824G>A p.A1942T | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs1429407555, COSV59445902; called by muse, mutect2, varscan2
- THSD4 | c.2494G>T p.E832* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99965509; called by muse, mutect2, varscan2
- WDR72 | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs368755797; called by muse, mutect2, varscan2
- ZFHX4 | c.5638A>G p.K1880E | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.829); catalogued as COSV51441187; called by muse, mutect2, varscan2
- OR6K3 | c.27del p.F9Lfs*17 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | called by mutect2, varscan2
- RYR1 | c.15021+2_15021+8del p.X5007_splice | Splice Site (DEL) | VAF 17/66 reads (26%) | called by mutect2, pindel, varscan2
- STAT6 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRAV6 | c.181A>C p.T61P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- AC006059.2 | c.1857G>A p.V619= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV59607499; called by muse, mutect2, varscan2
- AP1B1 | c.2406G>A p.S802= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs1443503483, COSV58018831; called by muse, mutect2, varscan2
- CNGB1 | c.3432G>A p.A1144= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as rs755577473, COSV51898313, COSV51902114; called by muse, mutect2, varscan2
- CYP2A13 | c.648G>A p.T216= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs748928501, COSV57838446; called by muse, mutect2, varscan2
- KCNJ4 | c.696C>T p.G232= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs779290700, COSV57856034; called by muse, mutect2, varscan2
- MVP | c.1086C>A p.P362= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV62422326; called by muse, mutect2, varscan2
- RUFY2 | c.426G>A p.A142= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs775819444, COSV61191472; called by muse, mutect2, varscan2
- SEC61A2 | c.126C>T p.F42= | Silent (SNP) | VAF 28/213 reads (13%) | catalogued as COSV100036403; called by muse, mutect2, varscan2
- TRAM1L1 | c.906G>T p.S302= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV60292002, COSV60292282; called by muse, mutect2, varscan2
- ZDBF2 | c.6684G>A p.S2228= | Silent (SNP) | VAF 24/28 reads (86%) | catalogued as rs769931510, COSV100985602, COSV65624129; called by muse, mutect2, varscan2
